Gene-level copy-number profile of tumor specimen TCGA-G9-6332-01A from TCGA case TCGA-G9-6332, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 55.2 years (20,166 days).
Specimen TCGA-G9-6332-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-PRAD.583b8007-12cc-4c42-a6d8-2ef36cdbadbc.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-G9-6332-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/5c0b501a-e670-4c71-aba0-a4e216ff8cae

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 39; copy number 1: 8; copy number 2: 4,610; copy number 3: 1,208; copy number 4: 53,353; copy number 5: 500; copy number 6: 96.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-G9-6332-01A-11D-1785-01): tumor purity 0.81, ploidy 1.96, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 39 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:124,059,794–124,536,348, 7 genes: LINC01170, HMGB1P29, AC016556.1, AC025465.2, AC025465.4, AC025465.3, AC025465.1.
- chr10:87,817,928–88,049,823, 8 genes: CFL1P1, RN7SL78P, KLLN, PTEN, AC063965.2, RPL11P3, AC063965.1, MED6P1.
- chr10:88,273,864–89,207,317, 24 genes (within-gene range 0–2): RNLS, Y_RNA, LIPJ, RPL7P34, LIPF, NAPGP1, LIPK, KRT8P38, LIPN, RCBTB2P1, LIPM, ANKRD22, PTCD2P2, STAMBPL1, ACTA2-AS1, ACTA2, AL157394.3, FAS, AL157394.2, AL157394.1, MIR4679-2, MIR4679-1, AL513533.1, CH25H.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 8. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
